Somatic mutation profile of tumor specimen C3N-02916-03 (aliquot CPT0215930006) from CPTAC case C3N-02916, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.9 years (21,891 days).
Specimen C3N-02916-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3d82416-eafb-473c-88d6-26bce33ab243.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02916-71 (Blood Derived Normal), aliquot CPT0216030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e29705d-97f8-4c79-8f81-ecb2ad2845a9

The open-access MAF lists 205 somatic variants for this specimen: 140 protein-altering or splice-affecting, 36 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 36, Intron 12, Nonsense Mutation 6, RNA 5, 5'Flank 5, 5'UTR 4, 3'UTR 2, Frame Shift Del 2, 3'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.793G>C p.G265R | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs397516905; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 28/281 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADD1 | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99297015; called by muse, mutect2
- ADGRA3 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs201250338; called by muse, mutect2
- APOB | c.1054G>T p.V352F | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51939700; called by muse, mutect2
- ATP6V1G3 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs1266446644; called by muse, mutect2
- ATP8A1 | c.3037G>T p.G1013W | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52536939; called by muse, mutect2
- BPIFB2 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs199499619, COSV50064185; called by muse, mutect2, varscan2
- CDH24 | c.1285G>C p.G429R | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57460929; called by muse, mutect2
- CHST13 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60043282; called by muse, mutect2, varscan2
- CSNK2A2 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV99345172; called by muse, mutect2, varscan2
- DIP2C | c.3460C>G p.H1154D | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV55180187; called by muse, mutect2
- EYA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CM111872; called by muse, mutect2
- HACE1 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV53508920; called by muse, mutect2
- HK1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 47/584 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.544); catalogued as rs367984091, COSV53861164; called by muse, mutect2
- IGKV1-5 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 74/490 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as rs764553380; called by muse, mutect2, varscan2
- KRTAP10-11 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 81/762 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs782180393; called by muse, mutect2, varscan2
- LRP2 | c.11668C>T p.R3890W | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373179621; called by muse, mutect2, varscan2
- MKRN3 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV58809896; called by muse, mutect2
- MYH1 | c.4365G>T p.K1455N | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV56858816; called by muse, mutect2, varscan2
- OR10Q1 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 27/313 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs746612596, COSV100372159, COSV57471918; called by muse, mutect2
- OR1A2 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67936700; called by muse, mutect2, varscan2
- OR5T2 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100507084; called by muse, mutect2, varscan2
- PAQR5 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); catalogued as rs1230455748; called by muse, mutect2, varscan2
- PLD6 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs1196645788; called by muse, mutect2
- SLC2A10 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1410197924, COSV63714584, COSV63715454; called by muse, mutect2
- ST8SIA6 | c.719T>A p.I240K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66467041; called by muse, mutect2
- TIAM2 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV59691702; called by muse, mutect2
- TMEM151B | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as rs1346502622; called by mutect2, varscan2
- TMPO | c.1743G>C p.Q581H | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV54125155; called by muse, mutect2
- TP53 | c.764_765del p.I255Nfs*8 | Frame Shift Del (DEL) | VAF 28/265 reads (11%) | catalogued as COSV53599946; called by muse*, mutect2
- TRIM64C | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV73267370; called by muse, mutect2, varscan2
- TRPV6 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100844418; called by muse, mutect2
- UNC5CL | c.1059G>C p.E353D | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99770886; called by muse, mutect2
- USP6 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV51483143; called by muse, mutect2
- ZFX | c.1559A>G p.K520R | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1393522258; called by muse, mutect2, varscan2
- ABCA12 | c.4682C>A p.P1561Q (on ENST00000272895 / NM_173076.3; = p.P1243Q on NM_015657.3) | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA8 | c.1951G>T p.G651W | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB9 | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.148); called by muse, mutect2
- ACKR1 | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTC1 | c.1126T>A p.C376S | Missense Mutation (SNP) | VAF 51/388 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ADCY4 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFF2 | c.1928T>G p.F643C | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); called by muse, mutect2
- AKAP6 | c.3929A>T p.K1310M | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- ANK2 | c.6019A>G p.K2007E | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ARHGAP26 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- BIVM-ERCC5 | c.1444A>T p.M482L | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- BTBD11 | c.3263C>A p.A1088D (on ENST00000280758 / NM_001018072.2; = p.A625D on NM_001017523.2) | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CARD9 | c.1270-2A>T p.X424_splice | Splice Site (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- CDH24 | c.1284A>T p.E428D | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- CNST | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2
- CTNNA2 | c.2378G>T p.S793I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CYP2E1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DHX37 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- DHX8 | c.3193A>G p.N1065D | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DLL1 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.414); called by muse, mutect2
- DNAH11 | c.2633A>G p.Q878R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.025); called by mutect2, varscan2
- DRD1 | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2
- ECH1 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2
- EP400 | c.9344A>T p.K3115M | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM205A | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- FASN | c.3928G>T p.A1310S | Missense Mutation (SNP) | VAF 107/436 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FBXO10 | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- FLG2 | c.3401G>C p.G1134A | Missense Mutation (SNP) | VAF 37/383 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.16); called by muse, mutect2
- GBE1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GDF6 | c.1053G>C p.R351S | Missense Mutation (SNP) | VAF 101/663 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GFOD1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GMEB2 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GPCPD1 | c.693dup p.D232* | Frame Shift Ins (INS) | VAF 24/195 reads (12%) | called by mutect2, pindel
- GPR142 | c.1186T>A p.L396M | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); called by muse, mutect2
- GPR26 | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 53/437 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- GRIK2 | c.2413C>T p.P805S | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.526); called by muse, mutect2
- HMGXB3 | c.1010A>G p.Y337C (on ENST00000613459; = p.Y91C on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HR | c.3110G>T p.G1037V | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2
- HRH2 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.173); called by muse, mutect2
- HTR3B | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); called by muse, mutect2
- IHH | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, mutect2
- IL17B | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- IMPG1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IMPG2 | c.691A>T p.I231L | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP4B | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2
- KALRN | c.3494A>G p.E1165G | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2
- KANSL3 | c.221C>G p.S74* | Nonsense Mutation (SNP) | VAF 21/268 reads (8%) | called by muse, mutect2
- KATNIP | c.2689C>T p.H897Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.341); called by muse, mutect2
- KRT3 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- KRTAP15-1 | c.365A>C p.Y122S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- MAGEF1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP4 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2
- MMP2 | c.1123T>A p.C375S | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPPED1 | c.762G>T p.W254C | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- MRPS30 | c.55C>G p.H19D | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- MTHFD1 | c.1597G>C p.V533L | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- MYRF | c.3184C>A p.L1062M (on ENST00000278836 / NM_001127392.3; = p.L1022M on NM_013279.4) | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NDST4 | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPNT | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.4076C>A p.P1359H | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NTNG2 | c.1366T>C p.C456R | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR12D2 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K1 | c.354G>C p.M118I | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- OR5B17 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2
- PAK1 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PARP6 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PHF20L1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PIP5K1C | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- PKHD1 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 32/433 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.111); called by muse, mutect2
- PLA1A | c.1225A>T p.K409* | Nonsense Mutation (SNP) | VAF 29/229 reads (13%) | called by muse, mutect2, varscan2
- PLBD2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PLD5 | c.1171C>A p.L391I (on ENST00000442594; = p.L329I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.71); called by muse, mutect2
- POU4F1 | c.1186A>G p.K396E | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PPP1R26 | c.3139A>G p.R1047G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PRKDC | c.5914G>C p.E1972Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRSS55 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PSMA2 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PSMC5 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 60/500 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM20 | c.393G>T p.Q131H | Missense Mutation (SNP) | VAF 56/480 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO2 | c.3168A>T p.K1056N | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RPS15 | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 19/535 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.443); called by muse, mutect2
- SCFD1 | c.356T>G p.I119S | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SGSM2 | c.216del p.F72Lfs*56 | Frame Shift Del (DEL) | VAF 37/262 reads (14%) | called by mutect2, pindel, varscan2
- SOGA3 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 17/203 reads (8%) | called by muse, mutect2
- SOX11 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SP100 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.255); called by muse, mutect2
- STARD13 | c.2779G>T p.G927* (on ENST00000336934 / NM_001243476.3; = p.G809* on NM_052851.3) | Nonsense Mutation (SNP) | VAF 39/377 reads (10%) | called by muse, mutect2, varscan2
- TAS2R14 | c.463A>G p.S155G | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2
- TEX13C | c.1889G>T p.S630I | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, varscan2
- TJP2 | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132E | c.2767G>T p.V923F (on ENST00000321639; = p.V1013F on NM_001304438.2) | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TUBA3C | c.1184T>G p.F395C | Missense Mutation (SNP) | VAF 13/429 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- UNC5A | c.1167C>G p.S389R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- USH2A | c.14195C>A p.P4732Q | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- VIL1 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- VN1R4 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.222); called by muse, mutect2
- XKR9 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFYVE16 | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ZNF112 | c.2307G>T p.R769S (on ENST00000337401 / NM_001083335.2; = p.R763S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF347 | c.1804T>G p.C602G | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF395 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 11/259 reads (4%) | called by muse, mutect2
- ZNF483 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- ZNF536 | c.2732G>C p.G911A | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF749 | c.1997A>G p.K666R | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ABCA4 | c.4476C>A p.T1492= | Silent (SNP) | VAF 16/239 reads (7%) | called by muse, mutect2
- ACSS2 | c.651C>T p.F217= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- ADAMTS18 | c.2374C>A p.R792= | Silent (SNP) | VAF 30/498 reads (6%) | catalogued as COSV51398816; called by muse, mutect2
- ADCYAP1R1 | c.399C>T p.A133= | Silent (SNP) | VAF 16/326 reads (5%) | catalogued as rs1369937585, COSV58445757; called by muse, mutect2
- AMBRA1 | c.2364C>T p.H788= (on ENST00000458649 / NM_001367468.1; = p.H698= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- CAPSL | c.531C>G p.T177= | Silent (SNP) | VAF 47/203 reads (23%) | catalogued as COSV101274166; called by muse, mutect2, varscan2
- CHD7 | c.2805A>G p.L935= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV101418255; called by muse, mutect2
- CKAP4 | c.1032G>T p.T344= | Silent (SNP) | VAF 54/398 reads (14%) | called by muse, mutect2
- CNGA3 | c.2031G>A p.L677= | Silent (SNP) | VAF 49/305 reads (16%) | called by muse, mutect2, varscan2
- DAAM2 | c.1110G>T p.T370= | Silent (SNP) | VAF 21/291 reads (7%) | catalogued as COSV51306421; called by muse, mutect2
- DCHS1 | c.9033T>G p.G3011= | Silent (SNP) | VAF 40/295 reads (14%) | called by muse, mutect2, varscan2
- GARNL3 | c.2106T>C p.V702= | Silent (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- GRAMD1B | c.111C>T p.D37= | Silent (SNP) | VAF 33/462 reads (7%) | called by muse, mutect2
- HTT | c.2313C>T p.L771= | Silent (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- IGSF10 | c.3063G>A p.R1021= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- IL17RC | c.873C>T p.N291= (on ENST00000295981 / NM_153461.4; = p.N205= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as rs769417200, COSV55972547; called by muse, mutect2, varscan2
- INPP5J | c.2916T>A p.G972= (on ENST00000331075 / NM_001284285.2; = p.G604= on NM_001002837.2) | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- LRRTM1 | c.819C>A p.P273= | Silent (SNP) | VAF 23/280 reads (8%) | called by muse, mutect2
- MAP3K19 | c.3657C>A p.T1219= | Silent (SNP) | VAF 29/181 reads (16%) | called by muse, mutect2, varscan2
- NAV2 | c.3546C>T p.V1182= (on ENST00000396087 / NM_001244963.2; = p.V1159= on NM_145117.5) | Silent (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- NCAN | c.2808C>T p.A936= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2, varscan2
- NLRP3 | c.1917C>T p.D639= | Silent (SNP) | VAF 43/397 reads (11%) | called by muse, mutect2, varscan2
- NTM | c.267C>T p.V89= | Silent (SNP) | VAF 18/432 reads (4%) | catalogued as COSV66172070; called by muse, mutect2
- OR10A5 | c.393G>A p.L131= | Silent (SNP) | VAF 48/382 reads (13%) | called by muse, varscan2
- PROM2 | c.1812G>T p.R604= | Silent (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2
- PTPN14 | c.945A>T p.P315= | Silent (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- RANBP2 | c.9537A>T p.A3179= | Silent (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- RYR2 | c.14820C>A p.V4940= | Silent (SNP) | VAF 20/72 reads (28%) | called by muse, varscan2
- SCN10A | c.3825G>A p.V1275= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs1434568924, COSV101479342; called by muse, mutect2
- SLC2A10 | c.60G>C p.L20= | Silent (SNP) | VAF 30/447 reads (7%) | called by muse, mutect2
- SLC8B1 | c.1515G>T p.L505= | Silent (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- SLX4 | c.210G>T p.V70= | Silent (SNP) | VAF 17/485 reads (4%) | called by muse, mutect2
- ST6GAL2 | c.225C>T p.D75= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV100867696; called by muse, mutect2
- TLNRD1 | c.426C>T p.P142= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1288840671; called by muse, mutect2, varscan2
- URGCP | c.1245C>T p.V415= (on ENST00000453200 / NM_001077663.3; = p.V406= on NM_017920.4) | Silent (SNP) | VAF 24/300 reads (8%) | catalogued as COSV56250037; called by muse, mutect2
- USH2A | c.14196A>C p.P4732= | Silent (SNP) | VAF 68/300 reads (23%) | catalogued as COSV56347964; called by muse, mutect2, varscan2
- AFDN | chr6:167976329 T>G | 3'Flank (SNP) | VAF 6/38 reads (16%) | catalogued as rs373603930; called by muse, varscan2
- AL137230.1 | n.502+1666A>T | Intron (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- AL353804.4 | chrX:73824578 T>A | 5'Flank (SNP) | VAF 15/110 reads (14%) | catalogued as rs373975235; called by muse, mutect2, varscan2
- AP002495.1 | c.436+28G>T | Intron (SNP) | VAF 49/311 reads (16%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+506A>T | Intron (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179768G>A | Intron (SNP) | VAF 42/311 reads (14%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1473+3303C>G | Intron (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- CTSL3P | n.158T>A | RNA (SNP) | VAF 20/220 reads (9%) | catalogued as rs749788149; called by muse, mutect2
- F13A1 | c.*7A>T | 3'UTR (SNP) | VAF 54/548 reads (10%) | called by muse, mutect2
- GRIN3A | c.-24G>T | 5'UTR (SNP) | VAF 24/420 reads (6%) | called by muse, mutect2
- HLA-L | n.676C>A | RNA (SNP) | VAF 35/368 reads (10%) | called by muse, mutect2
- IDH3A | chr15:78149339 G>T | 5'Flank (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- INAVA | c.-21T>A | 5'UTR (SNP) | VAF 64/252 reads (25%) | called by muse, mutect2, varscan2
- MIR182 | n.30A>G | RNA (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2, varscan2
- MIR4739 | chr17:79707432 G>T | 5'Flank (SNP) | VAF 28/301 reads (9%) | called by muse, mutect2
- MSL3P1 | n.968C>T | RNA (SNP) | VAF 48/301 reads (16%) | called by muse, mutect2, varscan2
- MTR | c.3405+51G>T | Intron (SNP) | VAF 53/238 reads (22%) | called by muse, mutect2
- PKD1L2 | chr16:81139677 G>C | 5'Flank (SNP) | VAF 17/270 reads (6%) | called by muse, mutect2
- PKN2 | c.1676+11G>A | Intron (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- PNKP | c.151+51C>T | Intron (SNP) | VAF 22/258 reads (9%) | called by muse, mutect2
- PTPRQ | chr12:80434967 A>C | 5'Flank (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- RAB43 | c.389-1155G>T | Intron (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- RNF5P1 | n.300G>C | RNA (SNP) | VAF 35/487 reads (7%) | called by muse, mutect2
- RPL37A | c.*14C>G | 3'UTR (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- SCNN1D | c.-516C>T | 5'UTR (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- SLC25A17 | c.335-5475G>T | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- SRSF5 | c.-85G>A | 5'UTR (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- SYNE2 | c.18038+748C>T | Intron (SNP) | VAF 20/268 reads (7%) | catalogued as rs919347903; called by muse, mutect2
- TTN | c.34265-4700T>C | Intron (SNP) | VAF 17/512 reads (3%) | called by muse, mutect2
